Somatic mutation profile of tumor specimen HTMCP-03-06-02246-01A (aliquot HTMCP-03-06-02246-01A-01D-6925) from CGCI case HTMCP-03-06-02246, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 33.8 years (12,342 days).
Specimen HTMCP-03-06-02246-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 347b3b69-e508-48db-aa97-1a5bf8b901f5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02246-10A (Blood Derived Normal), aliquot HTMCP-03-06-02246-10A-01D-6925; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22b19552-6c06-49d3-9552-a1b9f8e5c22e

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Nonsense Mutation 3, Intron 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs782430533; called by muse, mutect2, varscan2
- C1RL | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs771340998, COSV56923566; called by muse, mutect2, varscan2
- CSMD1 | c.9496C>T p.R3166* (on ENST00000520002; = p.R3165* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV59293387, COSV59386731; called by muse, mutect2, varscan2
- ERCC2 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs200438494; called by muse, mutect2, varscan2
- GTF3C2 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV53128967; called by mutect2, varscan2
- OCRL | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV100843318; called by muse, mutect2, varscan2
- U2SURP | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1195959930, COSV101204558; called by muse, mutect2, varscan2
- UTP20 | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383187013; called by muse, mutect2, varscan2
- ZFHX4 | c.4073C>G p.S1358* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | catalogued as COSV99255602; called by muse, mutect2, varscan2
- BIRC6 | c.952-1G>A p.X318_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- CCDC18 | c.2857G>A p.A953T (on ENST00000343253 / NM_001306076.1; = p.A954T on NM_206886.4) | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- EXOSC10 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.3179C>G p.T1060R | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCLO | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1A | c.4422C>T p.D1474= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs374555263; ClinVar: likely benign; called by mutect2, varscan2
- IFT122 | c.2127C>T p.A709= (on ENST00000348417 / NM_052989.3; = p.A650= on NM_018262.4) | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs73204231; called by muse, mutect2, varscan2
- MYO7B | c.672C>T p.S224= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs372953123; called by mutect2, varscan2
- OTOA | c.462C>T p.G154= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs767974412; ClinVar: uncertain significance; called by mutect2, varscan2
- TMPRSS6 | c.570C>T p.P190= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs773297269, COSV60977160; called by mutect2, varscan2
- WDFY4 | c.7920C>T p.I2640= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs920537665; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2463+1128C>T | Intron (SNP) | VAF 32/188 reads (17%) | catalogued as rs779907534; called by muse, mutect2, varscan2
- MTDHP2 | n.504A>C | RNA (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2
- TANC2 | c.212-42672C>T | Intron (SNP) | VAF 16/104 reads (15%) | catalogued as rs1328249543; called by muse, mutect2, varscan2
